CCDI case PBBNSH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6bd2a869-ac9c-4817-a9c7-8feb6251e146

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (548 days).

Biospecimens (2 samples)
- Sample 0DDHU6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DDHUH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
